Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8107, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8107-01A (Primary Tumor).

Microscopic

Sections designated as “parietal tumor or parietal pericystic” demonstrate infiltrating or mildly cellular diffuse glioma. The tumor cells are characterized by round nuclei that lack obvious processes and perinuclear halos. The sections that are designated as arising in one of two cysts show markedly hypercellular tumor with essentially identical histologic features. They do have modestly greater hyperchromasia but this may reflect cell density. Only rare mitotic figures are seen. There is no microvascular proliferation or necrosis.

Addendum

MIB-1 reactivity varies significantly within the tumor. It ranges from 0.7% in the least proliferative areas up to 9.7%. Whereas this is worrisome for early anaplastic progression, the diagnosis of grade III anaplastic oligodendroglioma cannot be made on this alone.

Diagnosis

Oligodendroglioma, grade II

Source: NCI Genomic Data Commons file c6de9b97-06ac-4da3-88da-0ee0fb95fc1f (TCGA-HT-8107.4E4564F4-1EBF-4D0D-A461-90F866C4EC42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).